Surgical pathology report (de-identified scan), TCGA case TCGA-BA-A4IF, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site UNC, specimen TCGA-BA-A4IF-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REVISED REPORT

Case Number :

Diagnosis:

Soft tissue, posterior hypopharyngeal wall, biopsy
- Invasive moderately differentiated keratinizing squamous cell carcinoma.
- High risk HPV in situ hybridization and p16 immunohistochemistry pending (A2).

Clinical History:

-year-old male with posterior wall oropharyngeal cancer. Per requisition: "Please do HPV testing".

Gross Description:

Received is one appropriately labeled container, additionally labeled "posterior hypopharyngeal wall" and is a 3.5 x 1.9 x 0.5 cm aggregate of spongy friable tan soft tissue fragments, blocks A1-A4,

ICD-0-3

Grossing Pathologist:

carcinoma, squamous cell, keratinizing, NOS 8071/3
Site: oropharynx, posterior wall C10.3

Light Microscopy:

Light microscopic examination is performed by Dr.

hw
10/3/12

For cases in which immunostains are performed, the following applies:

Appropriate internal and/or external positive and negative controls have been evaluated. Some of the immunohistochemical reagents used in this case may be classified as analyte specific reagents (ASR). These were developed and have performance characteristics determined by the Anatomic Pathology Department,

These reagents have not been cleared or approved by the US Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA-88) as qualified to perform high complexity clinical laboratory testing.

[page 2 of 2]
Procedures/Addenda:

Addendum

Addendum to add results of special studies.

Addendum Comment

Addendum Diagnosis:

Posterior hypopharyngeal wall, biopsy

- High risk HPV and p16 are negative; appropriate controls are performed.

Diagnostic Discrepancy		X
HPV Discrepancy		X

2/13/12

Source: NCI Genomic Data Commons file 16926989-eea8-43ec-87ce-a182e7b3e423 (TCGA-BA-A4IF.5092FCF9-0229-468C-B679-23FA2E422527.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).